Gene-level copy-number profile of tumor specimen C3L-08303-03 from CPTAC case C3L-08303, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.7 years (22,518 days).
Specimen C3L-08303-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53c40a4e-f52b-4b62-9651-d03fdc1c3cc3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08303-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/db361e34-b95e-4c4a-83fe-4e7f9fa41501

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,294; copy number 2: 49,493; copy number 3: 2,591; copy number 4: 394; copy number 5: 57; copy number 6: 51; copy number 15: 11; copy number 20: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 136 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:80,207,372–81,137,335, 20 genes, copy number 5: LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2.
- chr10:123,991,910–124,450,048, 6 genes, copy number 5: YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1.
- chr19:30,907,199–30,957,192, 2 genes, copy number 6: LINC01834, AC020897.1.
- chr20:38,210,503–38,772,520, 31 genes, copy number 5: KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173.
- chr20:52,671,735–57,712,780, 77 genes, copy number 6–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
